Somatic mutation profile of tumor specimen TCGA-34-8456-01A (aliquot TCGA-34-8456-01A-21D-2323-08) from TCGA case TCGA-34-8456, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.7 years (26,183 days).
Specimen TCGA-34-8456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8939e7f8-b20d-49b7-9e98-4a350f711826.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-8456-10A (Blood Derived Normal), aliquot TCGA-34-8456-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32226755-2da6-45c9-b177-c22799c5d6fb

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244197.3 | c.620T>G p.V207G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100558074; called by muse, mutect2, varscan2
- ADAMTS12 | c.3368C>A p.T1123K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.617); catalogued as COSV100711299; called by muse, mutect2
- ARSH | c.119G>C p.S40T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101139920; called by muse, mutect2, varscan2
- C14orf28 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs1163132008, COSV100290285; called by muse, mutect2
- CCDC7 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV53236135; called by muse, mutect2
- CLTRN | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100982211; called by muse, mutect2, varscan2
- FAM47A | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.5); catalogued as rs778609166, COSV100649727, COSV100649972; called by mutect2, varscan2
- GABRG1 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.956); catalogued as COSV54957288; called by muse, mutect2, varscan2
- GUCD1 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101238132; called by muse, mutect2, varscan2
- LRRN2 | c.942G>C p.K314N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65784589; called by muse, varscan2
- MAGED2 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99514653; called by muse, mutect2, varscan2
- PCLO | c.5558G>T p.R1853I | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100434423, COSV61662352; called by muse, varscan2
- PTPN5 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV100659942; called by muse, mutect2, varscan2
- SPAG1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773145801, COSV99309195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE4B | c.3331C>G p.P1111A (on ENST00000343090 / NM_001105562.3; = p.P982A on NM_006048.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV99477112; called by muse, mutect2, varscan2
- ZDHHC11 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99363161; called by muse, mutect2, varscan2
- ZFHX4 | c.3661T>C p.Y1221H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs748928480, COSV99264776; called by muse, mutect2, varscan2
- SRSF6 | c.378_381+4del p.X126_splice | Splice Site (DEL) | VAF 18/94 reads (19%) | called by mutect2, varscan2
- FAM9A | c.939G>A p.K313= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV101121359; called by muse, mutect2, varscan2
- FSTL5 | c.1026C>T p.V342= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1190567285, COSV100057800; called by muse, varscan2
- NOD1 | c.2037C>T p.Y679= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99768276; called by muse, mutect2, varscan2
- OGDHL | c.45T>A p.A15= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100934398; called by muse, mutect2
- OR8B8 | c.543C>T p.I181= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs868378941, COSV100045101; called by mutect2, varscan2
- SLC40A1 | c.1479T>C p.N493= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99656374; called by muse, mutect2
- SYNE1 | c.10842C>T p.L3614= (on ENST00000367255 / NM_182961.4; = p.L3621= on NM_033071.3) | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV99570687; called by muse, mutect2, varscan2
- DCHS2 | n.184T>C | RNA (SNP) | VAF 10/30 reads (33%) | catalogued as rs781485815, COSV100252340; called by muse, mutect2
